Surgical pathology report (de-identified scan), TCGA case TCGA-56-7731, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-56-7731-01A (Primary Tumor).

[page 1 of 2]
Surgical Pathology Report

* Final Report *

Result type:
Result date:
Result status:
Result title:
Performed by:
Verified by:
Encounter info:

*** Final Report ***

Clinical History

lung cancer; no prior biopsy at

Specimen

- #1 Pleural peel
- #2 Level 7 lymph node
- #3 10R lymph node
- #4 Right upper lobe with superior segment of lower lobe with stitch marking upper lobe, freeze for margins
- #5 Level 2R lymph node
- #6 4R lymph node

Gross Examination

#1 Labeled pleural peel is a 6.5 x 5.5 x up to 1.5 cm aggregate of multiple irregular fragments of pink-tan to gray glistening fibrous soft tissue. The tissue ranges from 0.1 cm up to 0.6 cm thick. There is a small amount of attached tan-yellow adipose tissue. Six representative sections submitted in three: "A"- "C".

#2 Labeled level 7 lymph node is a 2.2 x 1.7 x up to 0.4 cm aggregate of four irregular fragments of dark red to tan soft tissue, entirely submitted in one cassette.

#3 Labeled level 10R lymph node is a 1.3 x 0.7 x 0.5 cm ovoid portion of dark red to gray soft tissue, bisected, and entirely submitted in one cassette.

#4 Received fresh designated right upper lobe, superior segment of lower lobe, is one complex lobectomy specimen measuring 16.0 x 8.0 x 3.5 cm. There is a palpable mass present that is well defined with a tan cut surface and measuring 2.7 x 2.5 x 2.0 cm. The mass crosses the interlobar fissure and is 1.5 cm from the nearest bronchial margin, which is shaved as Frozen Section A. There is a 2.0 white pleural plaque in the apex, remote from the tumor. Representative sections of submitted for permanent section per the block summary. Block summary: "A", hilar nodes; "B", hilar vessels; "C,D", tumor with pleura; "E,F", tumor; "G", pleural plaque.

#5 Labeled level 2R lymph node is a 2.5 x 1.5 x 0.5 cm aggregate of multiple

Printed by:
Printed on:

Page 1 of 2
(Continued)

[page 2 of 2]
Surgical Pathology Report

* Final Report *

irregular fragments of gray-tan soft tissue and tan-yellow fibroadipose tissue. The tissue is entirely submitted in two: "A", "B".

#6 Labeled 4R lymph node is a 3.0 x 2.5 x up to 0.8 cm aggregate of multiple irregular fragments of dark gray-tan soft tissue and tan-yellow fibroadipose tissue. The tissue is entirely submitted in three: "A"- "C".

Frozen Section Diagnosis

#4 LUNG MASS, RIGHT UPPER AND LOWER LOBES, RESECTION (1FS): BRONCHIAL MARGIN WITH SMALL FOCUS OF LOW GRADE SQUAMOUS DYSPLASIA ON INITIAL SECTION, FOCUS DISAPPEARS ON DEEPER SECTIONS. REVIEWED WITH REPORTED AT

Microscopic Examination

#1-#6 Microscopic examination performed.

Final Diagnosis

#1 PLEURA, NOS, PEEL: BENIGN PLEURA WITH CHRONIC INFLAMMATION.

#2 LYMPH NODE, LEVEL 7, BIOPSY: NEGATIVE.

#3 LYMPH NODE, 10R, BIOPSY: NEGATIVE.

#4 LUNG MASS, RIGHT UPPER LOBECTOMY AND RIGHT LOWER LOBE SUPERIOR SEGMENTECTOMY:

INVASIVE SQUAMOUS CELL CARCINOMA.

HISTOLOGIC GRADE: MODERATELY TO POORLY DIFFERENTIATED, KERATINIZING.

TUMOR SIZE: 2.7 X 2.5 X 2.0 CM.

PROXIMAL BRONCHIAL RESECTION MARGIN STATUS: NEGATIVE.

PLEURAL SURFACE STATUS: NEGATIVE.

DIRECT EXTENSION OF TUMOR: TUMOR GROSSLY CROSSES INTERLOBAR FISSURE.

LYMPHOVASCULAR SPACE STATUS: NEGATIVE.

ADDITIONAL PATHOLOGIC FINDINGS: BENIGN APICAL PLEURAL PLAQUE.

LYMPH NODE STATUS: NEGATIVE HILAR NODES.

#5 LYMPH NODE, 2R, BIOPSY: NEGATIVE.

#6 LYMPH NODE, 4R, BIOPSY: NEGATIVE.

PATHOLOGIC STAGE (TNM CLASSIFICATION): pT2a pN0.

Signature Line

Ordering Provider

Ordering Physician:

Printed by:

Printed on:

Source: NCI Genomic Data Commons file 0a46b171-fb37-4d59-968a-acbba3634605 (TCGA-56-7731.AFDAABB6-B65A-44B9-867F-B22C405DF456.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).